Somatic mutation profile of tumor specimen MBCProject_3808_T1_WES (aliquot MBCProject_3808_T1_WES_1) from CMI case MBCProject_3808, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 67.5 years (24,661 days).
Specimen MBCProject_3808_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19efe79e-e4e1-48c1-9cff-2adba3bc3255.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3808_SALIVA (Saliva), aliquot MBCProject_3808_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55d4ec1b-c1e9-4a0e-9e00-36f72feeaec3

The open-access MAF lists 82 somatic variants for this specimen: 62 protein-altering or splice-affecting, 14 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 14, Nonsense Mutation 9, Intron 5, In Frame Del 2, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 54/189 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs104894104, CM014526, CX073790, COSV58704067, COSV58704478, COSV58719419; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL1A2 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 71/463 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72656396, CM070824, COSV51962571; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 14/69 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 91/276 reads (33%) | catalogued as rs1060500122, CM110149, COSV64288740, COSV64297241; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.572_574del p.P191del | In Frame Del (DEL) | VAF 26/188 reads (14%) | hotspot (GDC flag); catalogued as rs1555525902; called by pindel, varscan2
- ABCC3 | c.4216A>T p.T1406S | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.011); catalogued as rs778233657; called by muse, mutect2, varscan2
- ALG1L2 | c.286C>A p.L96I | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV70648974; called by muse, mutect2, varscan2
- CCR7 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs746049008, COSV55850387; called by muse, mutect2, varscan2
- CHRNA2 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1370103246; called by muse, mutect2, varscan2
- CLCN2 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs886403826, COSV55603976; called by muse, mutect2, varscan2
- COL6A6 | c.4522C>T p.R1508* | Nonsense Mutation (SNP) | VAF 18/128 reads (14%) | catalogued as rs369804734; called by muse, mutect2, varscan2
- CSMD1 | c.5336C>T p.A1779V (on ENST00000520002; = p.A1778V on NM_033225.6) | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs746370919, COSV104408935; called by muse, mutect2, varscan2
- CTNNA2 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as rs200794947, COSV63563934; called by muse, mutect2, varscan2
- DDX59 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs753527075, COSV58754543; called by muse, mutect2
- EVX2 | c.167C>G p.A56G | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.162); catalogued as COSV100420847; called by muse, mutect2, varscan2
- FGF23 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.447); catalogued as COSV52976418; called by muse, mutect2, varscan2
- GDF7 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV99694024; called by muse, mutect2
- GHSR | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV53841917; called by muse, mutect2
- GOLGA3 | c.3820G>T p.E1274* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as rs1025627053, COSV52639232; called by mutect2, varscan2
- HTR5A | c.1003C>G p.P335A | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99839458; called by muse, mutect2, varscan2
- HTT | c.3650G>A p.G1217D | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.802); catalogued as COSV61870444; called by mutect2, varscan2
- IFNA5 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs774150373; called by muse, mutect2, varscan2
- PKN2 | c.2866A>G p.I956V | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0.04); catalogued as COSV65142851; called by muse, varscan2
- RBMXL2 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs775110175, COSV60982312; called by muse, mutect2, varscan2
- RELN | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 52/275 reads (19%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.955); catalogued as rs910972681, COSV58986974; called by muse, mutect2, varscan2
- RHOA | c.354G>C p.K118N | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV69042274; called by muse, mutect2, varscan2
- SHOX | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs1425206026, CM011484; called by muse, mutect2, varscan2
- STAT1 | c.1048A>T p.K350* | Nonsense Mutation (SNP) | VAF 48/262 reads (18%) | catalogued as COSV61189656; called by muse, mutect2, varscan2
- TENM2 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs773543508, COSV72859296; called by muse, mutect2, varscan2
- TTN | c.12535C>T p.Q4179* (on ENST00000591111; = p.Q4133* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 26/282 reads (9%) | catalogued as COSV60465124; called by muse, mutect2
- AFF2 | c.1757G>C p.R586T | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.516); called by muse, mutect2
- ASNS | c.1289T>C p.L430S | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- CEP120 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- CHD7 | c.135dup p.G46Rfs*15 | Frame Shift Ins (INS) | VAF 28/244 reads (11%) | called by mutect2, pindel, varscan2
- CSMD2 | c.1705G>T p.A569S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.305); called by muse, varscan2
- CSNK1A1 | c.253_255del p.Y85del | In Frame Del (DEL) | VAF 21/152 reads (14%) | called by mutect2, pindel, varscan2
- CYP4V2 | c.358A>T p.K120* | Nonsense Mutation (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- DMD | c.7678C>A p.Q2560K | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.966); called by muse, mutect2
- EFCAB6 | c.2675G>T p.W892L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EML4 | c.1308G>T p.W436C | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EYS | c.7144A>C p.N2382H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- FAM227B | c.1180A>G p.I394V | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- FAM78B | c.609G>T p.Q203H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.138); called by mutect2, varscan2
- FBN2 | c.7709T>C p.I2570T | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- FN1 | c.1312G>C p.G438R | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRE | c.1306G>T p.G436C | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GTF3C1 | c.1786C>G p.L596V | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- HERC2 | c.1866G>C p.E622D | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0.006); called by muse, mutect2
- MVP | c.2108G>C p.R703P | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- OR52N2 | c.625G>T p.G209C | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- PGM1 | c.1280G>T p.R427M | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PRPF6 | c.1252G>T p.D418Y | Missense Mutation (SNP) | VAF 148/469 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ROBO1 | c.2047C>G p.P683A | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPGR | c.2267G>T p.R756L | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- RXFP1 | c.692A>G p.N231S | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SI | c.4491G>A p.W1497* | Nonsense Mutation (SNP) | VAF 36/299 reads (12%) | called by muse, mutect2, varscan2
- SPEG | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- SPRY2 | c.806dup p.Y269* | Nonsense Mutation (INS) | VAF 69/335 reads (21%) | called by mutect2, pindel, varscan2
- SPTBN1 | c.2069G>A p.R690H | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TTN | c.6061C>T p.R2021* (on ENST00000591111; = p.R1975* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- VN1R2 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZKSCAN4 | c.597G>C p.Q199H | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA3 | c.3771G>A p.L1257= | Silent (SNP) | VAF 18/150 reads (12%) | called by muse, mutect2
- ADAMTSL3 | c.1293C>G p.S431= | Silent (SNP) | VAF 43/174 reads (25%) | catalogued as COSV99716724; called by muse, mutect2, varscan2
- EBF2 | c.762C>T p.C254= | Silent (SNP) | VAF 10/43 reads (23%) | called by muse, varscan2
- FADS2 | c.1170C>G p.T390= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, varscan2
- FAT3 | c.12651C>T p.D4217= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs1268532489, COSV53123766; called by muse, mutect2, varscan2
- FGD1 | c.2370C>T p.H790= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV64309518; called by muse, mutect2, varscan2
- FRMD4B | c.2433C>T p.P811= | Silent (SNP) | VAF 23/178 reads (13%) | catalogued as COSV101273321; called by muse, mutect2, varscan2
- GLUD1 | c.534G>A p.P178= | Silent (SNP) | VAF 118/342 reads (35%) | catalogued as rs764675203; called by muse, mutect2, varscan2
- GRAMD2B | c.877C>T p.L293= | Silent (SNP) | VAF 20/178 reads (11%) | called by muse, mutect2, varscan2
- HNRNPA1 | c.108A>G p.Q36= | Silent (SNP) | VAF 61/358 reads (17%) | catalogued as rs28758594; called by muse, mutect2, varscan2
- NF1 | c.3663C>T p.L1221= | Silent (SNP) | VAF 48/225 reads (21%) | catalogued as rs771507034; called by muse, mutect2, varscan2
- OLFML2A | c.273C>T p.T91= | Silent (SNP) | VAF 15/157 reads (10%) | called by muse, mutect2, varscan2
- OTUD1 | c.282C>T p.G94= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- SIAH3 | c.225C>T p.H75= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs766432106; called by mutect2, varscan2
- DAZAP1 | c.1049-914C>G | Intron (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2, varscan2
- EIF2B5 | c.320+35C>G | Intron (SNP) | VAF 22/202 reads (11%) | called by muse, mutect2, varscan2
- MGP | c.-33C>G | 5'UTR (SNP) | VAF 38/370 reads (10%) | called by muse, mutect2
- NSD2 | c.761-4756A>G | Intron (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- TPM1 | c.563+28C>G | Intron (SNP) | VAF 23/112 reads (21%) | called by muse, varscan2
- ZNF8 | c.66+98C>G | Intron (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
